Gene-level copy-number profile of tumor specimen TCGA-61-1904-01A from TCGA case TCGA-61-1904, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.3 years (22,009 days).
Specimen TCGA-61-1904-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d51d1aba-7551-440d-b917-0ed23c8224dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1904-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/168982f0-9e89-4510-ae56-7360e6e4d06f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 975; copy number 2: 10,532; copy number 3: 15,521; copy number 4: 15,261; copy number 5: 7,250; copy number 6: 2,846; copy number 7: 2,415; copy number 8: 1,618; copy number 9: 1,729; copy number 10: 1,324; copy number 11: 185; copy number 13: 53; copy number 14: 28; copy number 16: 48; copy number 24: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1904-01A-01D-0577-01): tumor purity 0.58, ploidy 3.88, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:60,662,333–60,662,437, 1 gene: RNU6-623P.
- chr17:60,696,313–60,749,046, 3 genes: RN7SL606P, AC110602.1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 7,425 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,510,425–248,919,946, 486 genes, copy number 8–9 (broad region; genes not listed).
- chr3:90,030,284–117,139,389, 319 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr3:117,544,205–198,222,513, 1,478 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 7–10 (broad region; genes not listed).
- chr8:57,420,834–58,504,068, 17 genes, copy number 10: AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85.
- chr8:126,556,323–127,419,050, 1 gene, copy number 14 (within-gene range 5–14): PCAT1.
- chr8:126,766,196–145,066,685, 343 genes, copy number 9–16 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 8–10 (broad region; genes not listed).
- chr19:8,832,398–32,072,113, 906 genes, copy number 7–24 (within-gene range 6–24) (broad region; genes not listed).
- chr20:13,785,007–13,996,443, 3 genes, copy number 7: NDUFAF5, SEL1L2, RNU6-278P.
- chr20:14,003,508–14,223,325, 3 genes, copy number 7: RPS3P1, AIMP1P1, RN7SL864P.
- chr22:32,507,820–33,058,381, 5 genes, copy number 7 (within-gene range 5–7): SYN3, SYN3-AS1, RNA5SP497, Z73495.1, TIMP3.

Autosomal genes at a single copy (total copy number 1): 972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
